Somatic mutation profile of tumor specimen BA2209D (aliquot aq-BA2209D) from BEATAML1.0 case 2363, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.6 years (21,783 days).
Specimen BA2209D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a003493e-a3bb-43f2-84a5-334480c36f5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2919D (Solid Tissue Normal), aliquot aq-BA2919D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/660a38ae-fdf6-4fbc-832f-b4d7c8bab174

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284_307del p.P95_R102del | In Frame Del (DEL) | VAF 25/53 reads (47%) | hotspot (GDC flag); catalogued as rs766200080; called by mutect2, pindel, varscan2
- CRYBB1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745344551, COSV53232570; called by muse, mutect2, varscan2
- DDI1 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs371239684, COSV100160769, COSV56374601; called by muse, mutect2
- CATSPERB | c.1588-1G>T p.X530_splice | Splice Site (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- CMYA5 | c.2929T>C p.C977R | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); called by muse, mutect2
- HECW1 | c.2171G>A p.S724N | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MEIS1 | c.93G>C p.R31S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by mutect2, varscan2
- UPB1 | c.682A>T p.I228F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2
- DNAH2 | c.9864C>T p.G3288= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as rs143512388; called by muse, mutect2, varscan2
- MICAL3 | c.1191G>T p.G397= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- TAOK3 | c.1311G>T p.T437= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV101183671; called by muse, mutect2
- ZNF804A | c.3609C>T p.I1203= | Silent (SNP) | VAF 14/48 reads (29%) | called by mutect2, varscan2
